Gene-level copy-number profile of tumor specimen TCGA-IE-A6BZ-01A from TCGA case TCGA-IE-A6BZ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 65.0 years (23,756 days).
Specimen TCGA-IE-A6BZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.07440254-c4ae-43ec-8f9d-fdebdfc41021.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IE-A6BZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/201df4f5-6f66-4613-8970-14c8e7ac60dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 3,715; copy number 2: 24,279; copy number 3: 14,698; copy number 4: 12,936; copy number 5: 2,686; copy number 6: 1,239; copy number 7: 104; copy number 8: 142.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IE-A6BZ-01A-11D-A306-01): tumor purity 0.9, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:22,596,228–22,596,551, 1 gene: AC087241.1.
- chr17:7,613,946–7,854,796, 9 genes: SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3, DNAH2, RPL29P2, KDM6B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,899 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:10,365,593–11,382,348, 38 genes, copy number 5 (within-gene range 4–5): AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1.
- chr6:12,716,554–13,615,158, 11 genes, copy number 5 (within-gene range 4–5): PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1.
- chr6:20,212,087–47,309,905, 1,010 genes, copy number 5–6 (broad region; genes not listed).
- chr6:52,144,349–55,282,620, 77 genes, copy number 5 (broad region; genes not listed).
- chr7:112,206,695–155,966,343, 905 genes, copy number 5–6 (broad region; genes not listed).
- chr7:156,994,051–159,233,377, 38 genes, copy number 6–8 (within-gene range 4–8): MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:119,832,875–119,874,488, 5 genes, copy number 7: AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1.
- chr8:119,891,132–119,891,229, 1 gene, copy number 7: RNA5SP277.
- chr17:2,557,753–7,044,092, 194 genes, copy number 6 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).
- chr18:62,523,025–62,587,709, 1 gene, copy number 5 (within-gene range 3–5): ZCCHC2.
- chr18:62,551,203–63,381,629, 9 genes, copy number 5: AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1.
- chr18:71,519,962–72,638,521, 9 genes, copy number 5: LINC01541, AC090312.1, AC090312.2, LINC01899, AC027458.1, AC069114.1, AC069114.2, CBLN2, HNRNPA1P11.
- chr18:72,743,756–72,752,051, 2 genes, copy number 5: AC023301.1, RNA5SP460.
- chr18:73,151,241–74,160,531, 9 genes, copy number 5 (within-gene range 3–5): LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21.
- chr18:78,480,549–78,796,672, 4 genes, copy number 5: AC087399.1, AC012572.1, Y_RNA, AC044873.1.
- chr19:7,787,549–16,817,963, 514 genes, copy number 5–6 (broad region; genes not listed).
- chr19:27,681,072–44,636,781, 694 genes, copy number 5 (broad region; genes not listed).
- chr19:44,643,798–44,666,162, 2 genes, copy number 5 (within-gene range 4–5): PVR, MIR4531.

Autosomal genes at a single copy (total copy number 1): 3,715. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
